Somatic mutation profile of tumor specimen 0DDHU6 from CCDI case PBBNSH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (548 days).
Specimen 0DDHU6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d465231-a2e3-4afb-a41f-d5fb94a1181d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDHUH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3f73cb2-f9a0-43c7-b677-5835ca719f39

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C10orf71 | c.4207G>A p.G1403S | Missense Mutation (SNP) | VAF 95/763 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV60507794; called by muse, mutect2, varscan2
- SHPK | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 64/583 reads (11%) | catalogued as rs151138043; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- DEDD | c.*75C>A | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
